Somatic mutation profile of tumor specimen C3L-00942-01 (aliquot CPT0016830006) from CPTAC case C3L-00942, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.7 years (23,631 days).
Specimen C3L-00942-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9846429-cb35-4d25-8f81-ba19c6e60cea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00942-72 (Blood Derived Normal), aliquot CPT0016970001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccfb9d59-e823-4ffe-9cb3-48433d4ec952

The open-access MAF lists 145 somatic variants for this specimen: 92 protein-altering or splice-affecting, 37 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 37, Frame Shift Del 8, Nonsense Mutation 6, Intron 6, Splice Site 4, RNA 4, 3'UTR 4, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 138/596 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 58/303 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 53/326 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.14695G>A p.D4899N | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs794728807, COSV63711452; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALG13 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371858098, COSV52638435; called by muse, mutect2, varscan2
- ATP8B4 | c.2781+1G>A p.X927_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | catalogued as COSV52713028, COSV99463135; called by muse, mutect2, varscan2
- BAG6 | c.2965del p.Q989Sfs*85 (on ENST00000676571; = p.Q942Sfs*85 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/193 reads (8%) | catalogued as rs778695310; called by mutect2, pindel
- CCDC92 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53020137; called by muse, mutect2
- CYP11A1 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99165945; called by muse, mutect2, varscan2
- DIDO1 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1200484158, COSV56628036, COSV56634708; called by muse, mutect2, varscan2
- DLL1 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs944362947, COSV64536915; called by muse, mutect2
- ECM1 | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 19/568 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60871810; called by muse, mutect2
- FBRS | c.365C>T p.P122L (on ENST00000287468; = p.P642L on NM_001105079.3) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754944022; called by muse, mutect2, varscan2
- FGFRL1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 97/514 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs766259286; called by muse, varscan2
- FNDC7 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766393815; called by muse, mutect2, varscan2
- FUT5 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 34/662 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201842894; called by muse, mutect2
- GMIP | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs1477267848; called by muse, mutect2, varscan2
- GRIK2 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59736816; called by muse, mutect2
- HCN4 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545156905, COSV56083363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMCN1 | c.14620C>T p.R4874* | Nonsense Mutation (SNP) | VAF 50/157 reads (32%) | catalogued as rs748190962; called by muse, varscan2
- HSPA5 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61029462; called by muse, mutect2
- IKZF1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58792054; called by muse, mutect2
- KMT2D | c.16273G>A p.E5425K | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM146878, COSV56454472; called by muse, mutect2
- LOXHD1 | c.3472G>A p.G1158S | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as rs1054290922; called by muse, mutect2, varscan2
- LRP1B | c.6536G>A p.G2179E | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1379417709, COSV101259241, COSV67226136; called by muse, mutect2, varscan2
- ME1 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs546194192, COSV63840994; called by muse, mutect2, varscan2
- MECOM | c.729C>G p.N243K (on ENST00000468789 / NM_001105078.4; = p.N431K on NM_004991.4) | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1387015338; called by muse, mutect2, varscan2
- MIP | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57511685; called by muse, mutect2, varscan2
- MUC17 | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs766331025; called by muse, mutect2, varscan2
- NALCN | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV51945560; called by muse, mutect2
- NOLC1 | c.1378A>G p.K460E | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV64180927; called by muse, mutect2
- OR6P1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 107/267 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as rs776951618, COSV58109037; called by muse, mutect2, varscan2
- PTBP1 | c.959_970del p.A320_A323del (on ENST00000349038 / NM_031991.4; = p.A346_A349del on NM_002819.5) | In Frame Del (DEL) | VAF 21/134 reads (16%) | catalogued as rs756707129; called by mutect2, varscan2
- SALL4 | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as rs377696653; called by muse, mutect2, varscan2
- SHISAL1 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs777404839, COSV66988373, COSV66989023; called by muse, mutect2, varscan2
- SHROOM2 | c.1358A>G p.Q453R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.439); catalogued as COSV66606600; called by muse, mutect2, varscan2
- SPSB4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs1457468003, COSV100141745; called by muse, mutect2, varscan2
- SSTR5 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99559798; called by muse, mutect2
- TENT5D | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs992431399, COSV57638777; called by muse, mutect2
- TMCC2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 91/663 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV100405618; called by muse, mutect2, varscan2
- TRIM29 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 13/387 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1159637629; called by muse, mutect2
- TSHZ1 | c.197C>T p.S66F (on ENST00000580243 / NM_001308210.2; = p.S21F on NM_005786.6) | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs1371484603; called by muse, mutect2
- UPRT | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 29/156 reads (19%) | catalogued as rs368655148, COSV64920607; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 23/167 reads (14%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- ZNF541 | c.692del p.P231Rfs*49 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | catalogued as rs780386192; called by mutect2, pindel
- ABCC9 | c.4364A>G p.Q1455R | Missense Mutation (SNP) | VAF 25/479 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ANKRD24 | c.2689C>T p.Q897* | Nonsense Mutation (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- ARID1A | c.4680_4687del p.V1561Hfs*8 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel
- CD200R1L | c.229del p.C77Afs*22 | Frame Shift Del (DEL) | VAF 70/368 reads (19%) | called by mutect2, varscan2
- CLK2 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2
- CLSTN3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); called by muse, mutect2
- CRHR1 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2
- CTNNA3 | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.122); called by muse, mutect2
- DHX38 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUS3L | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.071); called by muse, mutect2
- EPG5 | c.7687C>T p.L2563F | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPHA10 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB2 | c.2903T>A p.L968Q (on ENST00000400191 / NM_001309193.2; = p.L969Q on NM_004442.7) | Missense Mutation (SNP) | VAF 23/524 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ETV6 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FABP9 | c.329T>G p.V110G | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM234B | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2
- FAM25A | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- FERD3L | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- GBP7 | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2
- GPT | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECTD1 | c.4618A>G p.R1540G | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); called by muse, mutect2
- KCNA6 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KRT27 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, varscan2
- LENG8 | c.1240T>G p.S414A | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MED12 | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- NAXE | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- NEFM | c.2267A>G p.H756R | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- NIBAN3 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); called by muse, mutect2
- NSD1 | c.824del p.N275Ifs*15 | Frame Shift Del (DEL) | VAF 29/138 reads (21%) | called by mutect2, pindel, varscan2
- NUGGC | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OLFML3 | c.61G>T p.G21* | Nonsense Mutation (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- OR51A2 | c.186C>G p.Y62* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- POLD1 | c.2959del p.X987_splice | Splice Site (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel
- PRDM10 | c.2470del p.Q824Sfs*2 | Frame Shift Del (DEL) | VAF 14/195 reads (7%) | called by mutect2, pindel
- RNASEH2A | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF43 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A11 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC7A9 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 28/657 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); called by muse, mutect2
- SPATA31E1 | c.3916A>T p.R1306W | Missense Mutation (SNP) | VAF 14/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ST6GALNAC2 | c.296dup p.A100Sfs*74 | Frame Shift Ins (INS) | VAF 16/152 reads (11%) | called by mutect2, pindel
- TBRG4 | c.1177-1G>T p.X393_splice | Splice Site (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- TRIM32 | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); called by muse, mutect2
- TTN | c.9746C>T p.T3249I (on ENST00000591111; = p.T3203I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/174 reads (5%) | PolyPhen possibly damaging (0.775); called by muse, mutect2
- VARS2 | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- VPS25 | c.37T>C p.F13L | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- ZNF696 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- ZNF839 | c.1941del p.P648Lfs*17 (on ENST00000558850 / NM_001267827.1; = p.P764Lfs*17 on NM_018335.5) | Frame Shift Del (DEL) | VAF 10/120 reads (8%) | called by mutect2, pindel
- AMIGO2 | c.1218C>T p.C406= | Silent (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- ANKRD11 | c.7398C>T p.Y2466= | Silent (SNP) | VAF 20/385 reads (5%) | catalogued as rs1234571808, COSV56359471; called by muse, mutect2
- ANXA7 | c.63T>C p.G21= | Silent (SNP) | VAF 7/181 reads (4%) | catalogued as COSV65822941; called by muse, mutect2
- C1QTNF9B | c.510G>T p.G170= | Silent (SNP) | VAF 30/352 reads (9%) | called by muse, mutect2
- C2orf72 | c.102G>A p.L34= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- CARD11 | c.1494C>T p.R498= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- CCN6 | c.393T>C p.N131= | Silent (SNP) | VAF 24/744 reads (3%) | catalogued as rs1554313564; called by muse, mutect2
- CHAF1A | c.2736C>T p.G912= | Silent (SNP) | VAF 40/229 reads (17%) | catalogued as rs745730810, COSV100011169; called by muse, mutect2, varscan2
- CLTCL1 | c.750G>T p.V250= | Silent (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- CYP4F12 | c.1530C>T p.G510= | Silent (SNP) | VAF 68/220 reads (31%) | catalogued as rs374696674; called by muse, mutect2, varscan2
- DLG5 | c.984C>T p.V328= | Silent (SNP) | VAF 36/740 reads (5%) | catalogued as rs367819703; called by muse, mutect2
- DNAH14 | c.189G>A p.L63= | Silent (SNP) | VAF 12/330 reads (4%) | catalogued as rs1355735297; called by muse, mutect2
- F9 | c.1083C>T p.H361= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as rs1333808596, COSV99496636; called by muse, mutect2
- GIT1 | c.1038C>T p.D346= | Silent (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- GTF2E1 | c.804A>G p.S268= | Silent (SNP) | VAF 38/287 reads (13%) | catalogued as rs111488033; called by muse, mutect2, varscan2
- HBE1 | c.183C>A p.V61= | Silent (SNP) | VAF 81/455 reads (18%) | catalogued as rs202160057; called by muse, mutect2, varscan2
- HIPK4 | c.1797T>C p.H599= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- HSPG2 | c.3195G>A p.Q1065= | Silent (SNP) | VAF 35/691 reads (5%) | catalogued as rs1465732500; called by muse, mutect2
- IRF2BPL | c.1255C>T p.L419= | Silent (SNP) | VAF 10/215 reads (5%) | catalogued as rs1327557938; called by muse, mutect2
- LTK | c.1254G>A p.L418= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as rs1266794036; called by muse, mutect2
- MPV17L2 | c.147C>T p.I49= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- NYX | c.729C>T p.A243= | Silent (SNP) | VAF 36/172 reads (21%) | called by muse, mutect2, varscan2
- OTOP2 | c.1104C>T p.D368= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as rs768778471, COSV58882465; called by muse, mutect2, varscan2
- PDCD11 | c.2670G>A p.Q890= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- PELP1 | c.2508A>G p.P836= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs971124924; called by muse, mutect2
- PEX6 | c.306G>T p.A102= | Silent (SNP) | VAF 110/465 reads (24%) | catalogued as rs727504083; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PPP1R3G | c.538C>T p.L180= | Silent (SNP) | VAF 39/198 reads (20%) | called by muse, mutect2, varscan2
- PRSS45P | c.495C>A p.P165= | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- SLC16A12 | c.1188A>G p.V396= | Silent (SNP) | VAF 21/601 reads (3%) | called by muse, mutect2
- TAF1L | c.1587T>C p.I529= | Silent (SNP) | VAF 15/261 reads (6%) | called by muse, mutect2
- TBC1D13 | c.708G>C p.G236= | Silent (SNP) | VAF 68/393 reads (17%) | called by muse, mutect2, varscan2
- TYMP | c.1173G>A p.L391= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as rs1385879743; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP35 | c.135C>T p.G45= | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- XKR6 | c.489G>A p.G163= | Silent (SNP) | VAF 23/454 reads (5%) | catalogued as rs780448106, COSV52009526; called by muse, mutect2
- ZBTB17 | c.636C>A p.A212= | Silent (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- ZFYVE26 | c.3375C>T p.H1125= | Silent (SNP) | VAF 115/498 reads (23%) | called by muse, mutect2, varscan2
- ZNF775 | c.588C>T p.C196= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs1354662002; called by muse, mutect2
- ASH1L | c.5828+4953G>A | Intron (SNP) | VAF 64/344 reads (19%) | catalogued as rs530496991; called by muse, mutect2, varscan2
- DST | c.4297-3756C>T | Intron (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- FAM86C1P | n.400C>A | RNA (SNP) | VAF 39/614 reads (6%) | called by muse, mutect2
- FMR1 | c.*700A>G | 3'UTR (SNP) | VAF 5/86 reads (6%) | catalogued as rs782151729; called by muse, mutect2
- GCNT2 | chr6:10634225 T>C | 3'Flank (SNP) | VAF 16/211 reads (8%) | called by muse, mutect2
- GUSBP10 | n.140C>T | RNA (SNP) | VAF 34/199 reads (17%) | catalogued as rs567835031; called by muse, mutect2, varscan2
- KMT5C | c.570+1018C>T | Intron (SNP) | VAF 22/432 reads (5%) | catalogued as rs981495198; called by muse, mutect2
- MIR129-2 | n.10C>T | RNA (SNP) | VAF 22/445 reads (5%) | called by muse, mutect2
- NAGA | c.-56C>G | 5'UTR (SNP) | VAF 13/343 reads (4%) | catalogued as rs1390962338; called by muse, mutect2
- RAE1 | c.1020+231C>T | Intron (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- RASGRP2 | c.-71-151C>A | Intron (SNP) | VAF 12/286 reads (4%) | catalogued as rs1303935541; called by muse, mutect2
- RPL13AP20 | n.217C>A | RNA (SNP) | VAF 18/284 reads (6%) | called by muse, mutect2
- TECPR2 | c.*808C>T | 3'UTR (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- TMEM135 | c.*514T>C | 3'UTR (SNP) | VAF 26/564 reads (5%) | called by muse, mutect2
- TMEM184A | c.644+253C>A | Intron (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- ZMIZ1 | c.*1369A>G | 3'UTR (SNP) | VAF 26/548 reads (5%) | called by muse, mutect2
